Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EY, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EY-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
807013
Site: Esophagus, distal third
c15.5
JW 11/24/14

Collect date:

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus

1 - "Transmediastinal esophagectomy":

- Well differentiated squamous cell carcinoma, measuring 8.5 x 5.5cm, ulcerative-vegetative, infiltrating the wall until periesophagic adipose tissue, located in the distal third of the esophagus, extending to the cardia;
- Vascular and perineural invasions undetected;
- Mild peritumoral inflammatory infiltrate;
- Moderate peritumoral desmoplasia;
- Proximal and distal surgical margins uninvolved by neoplasia;
- Chronic esophagitis and chronic gastritis associated;
- Absence of metastasis on the examined lymph node of the chain 1 (0/1), 6 lymph nodes examined of the chain 2 (0/6), 12 examined on the chain 3 (0/12), 6 examined of the chain 7 (0/6), 4 examined of the chain 9 (0/4) and 3 examined of the chain 110 (0/3);
- Absence of lymph node chain 5 in designated material .

2 - "Esophageal margin":

- Uninvolved by neoplasia.

PATHOLOGYC STAGING: pT3 pN0

Y1: Tumor Site Discrepancy		☒
Y1PAA Discrepancy		☒

Source: NCI Genomic Data Commons file b74f2006-e69d-4bb2-9c0f-63d773234c67 (TCGA-VR-A8EY.6A2DC852-B42E-4B24-98EC-9E8441063AC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).